Gene-level copy-number profile of tumor specimen TARGET-10-PASJYI-09A from TARGET case TARGET-10-PASJYI, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.3 years (5,228 days).
Specimen TARGET-10-PASJYI-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.d447f71d-a9ac-55cc-a8f4-e72a9ca69bbc.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PASJYI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 350 have no estimate.
https://portal.gdc.cancer.gov/files/6779e447-6111-4562-b242-442929c959c8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,434; copy number 2: 57,303; copy number 3: 532; copy number 4: 2; copy number 18: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:1,561,385–1,620,061, 2 genes, copy number 18 (within-gene range 2–18): SIRPB1, AL049634.3.

Autosomal genes at a single copy (total copy number 1): 49. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
